Somatic mutation profile of tumor specimen TCGA-B0-5110-01A (aliquot TCGA-B0-5110-01A-01D-1421-08) from TCGA case TCGA-B0-5110, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 71.1 years (25,976 days).
Specimen TCGA-B0-5110-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 875b2ad4-c9ea-4cc6-a47e-ff167a80e988.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5110-11A (Solid Tissue Normal), aliquot TCGA-B0-5110-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74472302-b5e7-4beb-8076-924cda979254

The open-access MAF lists 67 somatic variants for this specimen: 53 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 12, Frame Shift Del 9, Nonsense Mutation 2, Splice Region 1, 5'Flank 1, Splice Site 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.4018C>A p.Q1340K | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV53984353; called by muse, mutect2, varscan2
- AGBL1 | c.2351G>C p.S784T | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.812); catalogued as COSV66866094, COSV66871285; called by muse, mutect2, varscan2
- ANAPC5 | c.1515+1G>T p.X505_splice | Splice Site (SNP) | VAF 46/168 reads (27%) | catalogued as COSV55845151, COSV99029002; called by muse, mutect2, varscan2
- BEND2 | c.1012G>C p.V338L | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV66217090; called by muse, mutect2
- BIRC6 | c.1445G>A p.S482N | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs550400928, COSV70205003; called by muse, mutect2, varscan2
- BRINP2 | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768682042, COSV64179715; called by muse, mutect2, varscan2
- BSPRY | c.1024C>A p.H342N | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.048); catalogued as COSV53058149; called by muse, mutect2, varscan2
- C10orf62 | c.617G>C p.S206T | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV65705539; called by muse, mutect2, varscan2
- CCBE1 | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 78/304 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM098496, COSV67951377; called by muse, mutect2, varscan2
- CLCA1 | c.558A>G p.R186= | Splice Region (SNP) | VAF 10/81 reads (12%) | catalogued as COSV52330822; called by muse, varscan2
- EHBP1 | c.1150T>A p.L384M | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.332); catalogued as COSV50419435, COSV50424099; called by muse, mutect2, varscan2
- EIF5 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.011); catalogued as COSV53686638; called by muse, mutect2, varscan2
- ERBB2 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV54081753; called by muse, mutect2, varscan2
- FGF6 | c.328C>A p.H110N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57405088; called by muse, mutect2
- GABRQ | c.806T>C p.L269P | Missense Mutation (SNP) | VAF 199/897 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV64783726; called by muse, mutect2, varscan2
- GLB1 | c.940T>G p.F314V | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM156650, COSV56567568; called by muse, mutect2, varscan2
- HOXB4 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60178688, COSV60178961; called by muse, mutect2, varscan2
- HR | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 49/211 reads (23%) | catalogued as COSV57194546; called by muse, mutect2, varscan2
- HS3ST2 | c.830T>A p.L277H | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54466058; called by muse, mutect2
- ILVBL | c.1278C>A p.D426E | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.134); catalogued as rs752537179, COSV54622281; called by muse, mutect2
- KATNA1 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV59503826; called by muse, mutect2, varscan2
- KBTBD7 | c.1132C>A p.H378N | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs762281112, COSV65266092, COSV65267126; called by muse, mutect2, varscan2
- KCTD8 | c.380A>G p.K127R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV63595580; called by muse, mutect2, varscan2
- KDM3A | c.3307G>A p.A1103T | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57225269; called by muse, mutect2, varscan2
- KIAA0319L | c.2018G>A p.R673K | Missense Mutation (SNP) | VAF 93/353 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.856); catalogued as rs766966340, COSV57850086; called by muse, mutect2, varscan2
- LRRCC1 | c.1988A>G p.N663S | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV64485492; called by muse, mutect2, varscan2
- MAN2B2 | c.2107G>C p.E703Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV53456451; called by muse, mutect2, varscan2
- MYO16 | c.2699C>T p.T900I | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.061); catalogued as rs764612209, COSV51815928; called by muse, mutect2, varscan2
- NDUFS2 | c.474G>T p.L158F | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV63488651; called by muse, mutect2
- NRXN1 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 25/334 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.768); catalogued as COSV58460352, COSV58488351; called by muse, mutect2
- OAF | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 25/125 reads (20%) | catalogued as COSV61109906; called by muse, mutect2, varscan2
- OAS3 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs774201013, COSV57445151; called by muse, mutect2, varscan2
- OR5D14 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 71/328 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV59458314; called by muse, mutect2, varscan2
- OR5T2 | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758178475, COSV57590768; called by muse, mutect2, varscan2
- OR7A10 | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.059); catalogued as rs1389566172, COSV50166774; called by muse, mutect2, varscan2
- OTUD4 | c.1720C>T p.P574S (on ENST00000447906 / NM_001366057.1; = p.P509S on NM_001102653.1) | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV71382267; called by muse, mutect2, varscan2
- PRMT6 | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV63656396; called by muse, mutect2, varscan2
- PROSER1 | c.2075C>T p.P692L | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61489438; called by muse, mutect2, varscan2
- SIPA1L2 | c.5017C>T p.R1673W | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs1302135006, COSV53387000; called by muse, mutect2, varscan2
- SLC5A2 | c.271A>G p.S91G | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs374586198; called by muse, varscan2
- SOX7 | c.1078G>T p.V360L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV58731569, COSV58731937, COSV58731945; called by muse, mutect2, varscan2
- TRAV17 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.282); catalogued as rs371505326; called by muse, mutect2, varscan2
- ZSCAN5A | c.1491A>G p.*497Wext*14 | Nonstop Mutation (SNP) | VAF 74/256 reads (29%) | catalogued as COSV54231338; called by muse, mutect2, varscan2
- AKAP9 | c.7158del p.E2386Dfs*11 (on ENST00000359028; = p.E2362Dfs*11 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/193 reads (22%) | called by mutect2, pindel, varscan2
- CCDC15 | c.79del p.D27Tfs*13 | Frame Shift Del (DEL) | VAF 45/229 reads (20%) | called by mutect2, pindel, varscan2
- CHD9 | c.4263del p.F1422Sfs*11 | Frame Shift Del (DEL) | VAF 41/201 reads (20%) | called by mutect2, pindel, varscan2
- DIAPH1 | c.3153del p.A1052Lfs*8 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel
- MXRA5 | c.3232_3241del p.T1078Efs*22 | Frame Shift Del (DEL) | VAF 59/292 reads (20%) | called by mutect2, pindel, varscan2
- MYH2 | c.5298del p.D1767Mfs*4 | Frame Shift Del (DEL) | VAF 47/282 reads (17%) | called by mutect2, pindel, varscan2
- NOMO3 | c.2332T>G p.S778A | Missense Mutation (SNP) | VAF 73/597 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.022); called by muse, varscan2
- PBRM1 | c.4207_4208del p.D1403Lfs*18 (on ENST00000296302 / NM_001366071.2; = p.D1351Lfs*18 on NM_018313.5) | Frame Shift Del (DEL) | VAF 52/299 reads (17%) | called by mutect2, pindel, varscan2
- QTRT1 | c.514del p.E172Rfs*46 | Frame Shift Del (DEL) | VAF 53/237 reads (22%) | called by mutect2, pindel, varscan2
- THSD7B | c.1470_1471del p.W490Cfs*9 | Frame Shift Del (DEL) | VAF 27/155 reads (17%) | called by mutect2, pindel, varscan2
- ADD3 | c.534C>T p.G178= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as COSV53325602; called by muse, mutect2, varscan2
- CACNB1 | c.1206G>A p.A402= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs771166354, COSV100703351, COSV60000135; called by muse, mutect2, varscan2
- CCNC | c.150A>T p.A50= | Silent (SNP) | VAF 58/225 reads (26%) | catalogued as COSV58334903; called by muse, mutect2, varscan2
- HIP1R | c.2313C>T p.S771= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV53444571; called by muse, mutect2, varscan2
- KLHL6 | c.1305C>A p.I435= | Silent (SNP) | VAF 115/486 reads (24%) | catalogued as COSV100384499, COSV58069151; called by muse, mutect2, varscan2
- PABPC5 | c.774C>T p.D258= | Silent (SNP) | VAF 65/254 reads (26%) | catalogued as rs1446092065, COSV57042728, COSV57043054; called by muse, mutect2, varscan2
- PIK3AP1 | c.1305C>T p.L435= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as COSV59536709; called by muse, mutect2, varscan2
- SLC35G6 | c.318C>T p.F106= | Silent (SNP) | VAF 105/407 reads (26%) | catalogued as COSV59495637; called by muse, mutect2, varscan2
- SLC7A4 | c.279G>A p.G93= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1447159421, COSV60385946; called by mutect2, varscan2
- SRSF4 | c.1344C>G p.S448= | Silent (SNP) | VAF 89/345 reads (26%) | catalogued as COSV65695605; called by muse, mutect2, varscan2
- VEZT | c.1137A>G p.Q379= | Silent (SNP) | VAF 129/553 reads (23%) | catalogued as COSV54144639; called by muse, mutect2, varscan2
- ZFPL1 | c.678C>A p.L226= | Silent (SNP) | VAF 33/145 reads (23%) | catalogued as rs1372646409, COSV51869372, COSV51871103; called by muse, mutect2, varscan2
- ACSM3 | c.1326+194C>A | Intron (SNP) | VAF 28/129 reads (22%) | catalogued as COSV55503877; called by muse, mutect2, varscan2
- KRTCAP2 | chr1:155173293 del CTA | 5'Flank (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
